Surgical pathology report (de-identified scan), TCGA case TCGA-55-7816, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7816-01A (Primary Tumor).

[page 1 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. LUNG, RIGHT UPPER LOBE, WEDGE EXCISION:
- ADENOCARCINOMA, SEE COMMENT.

B. PLEURA, BIOPSY:
- ADENOCARCINOMA, SEE COMMENT.

C. LUNG, RIGHT LOWER LOBE, WEDGE EXCISION:
- ADENOCARCINOMA, SEE COMMENT.

D. PLEURA, BIOPSY:
- ADENOCARICNOMA, SEE COMMENT.

COMMENT (Parts A-D): Sections show a histologically similar moderately differentiated adenocarcinoma in all specimens. Immunohistochemistry was performed on part A and shows the tumor cells to be positive for TTF-1, CK7, Napsin-A, MOC-31 and ER (rare positive), and negative for calretinin, CDX2, CK20, CK 5/6, GCDFP-15, mammaglobin, p63, PAX-8, vilin and S-100. The histomorphology and immunohistochemistry staining pattern are consistent with a lung primary adenocarcinoma. Results discussed with Dr.

Source of Specimen:

- A. Lung; Wedge Excision Right Upper Lobe
- B. Pleural
- C. Lung; Wedge Excision Right Lower Lobe
-

[page 2 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Clinical History/Operative Dx:

Right lung nodule

Intraoperative Diagnosis:

A. Right lung nodule: Non-small cell carcinoma.

B. Pleural biopsy: Poorly differentiated carcinoma (Dr. [REDACTED]). The intraoperative interpretation(s) was/were performed and rendered at [REDACTED].

Gross Description:

A. Part A is labeled wedge excision right upper lobe for frozen section. Received in the fresh state for frozen section analysis is a 3.5 x 2.2 x 1.0 cm wedge of lung. The pleura is glistening, light pink and tan. Numerous surgical staples are present along one periphery, involving approximately 4 mm of lung tissue, now trimmed and the resulting margin marked black. The specimen is serially sectioned demonstrating a partially circumscribed, yellow-gray nodule, 1.2 x 1.1 x 1.0 cm, grossly within 0.2 cm of the margin now marked black. Representative sections are submitted for frozen section analysis and the residual frozen tissue submitted in A1 for permanent sections. The lesion appears to abut the overlying pleura. The adjacent lung parenchyma is spongy, light pink and tan. The remainder of the specimen is submitted for microscopic evaluation, excluding the remnant involved with surgical staples.

Cassette summary: A1) frozen section tumor nodule, A2) remainder of wedge including lesion submitted. [REDACTED]

B. Part B is labeled pleural biopsy. Received in the fresh state for frozen section analysis are two pieces of flimsy to rubbery, pink and tan soft tissue, measuring in aggregate 1.8 x 1.3 x 0.3 cm. The tissue is entirely submitted for frozen section analysis, the residual frozen tissue entirely submitted in B1 for permanent sections [REDACTED].

C. Part C is labeled excision right lower lobe. Received in formalin is a wedge of lung, 3.3 x 1.3 x 0.5 cm and less than 1 gram. The pleura is glistening, light tan and congested purple-tan. A palpable area of nodularity is noted along the mid pleural surface. The surgical staples involve approximately 5 mm of lung tissue, now trimmed, and the resulting margin is marked black. The specimen is serially sectioned through the margin now marked black to reveal two circumscribed, bluish-gray areas of fibrous appearing nodularity, 0.5 cm and 0.4 cm each. The specimen is entirely submitted for microscopic evaluation in C1 and C2. [REDACTED]

D. Part D is labeled pleural biopsy. Received in formalin are two soft to rubbery, triangular fragments of light gray-tan fibrous appearing soft tissue, 0.6 x 0.4 x 0.2 cm and 2.3 x 0.4 x 0.2 cm each. Both fragments are submitted in D1. [REDACTED]

Microscopic Description:

[REDACTED]

[page 3 of 3]
FINAL SURGICAL PATHOLOGY REPORT

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Immunohistochemistry was performed with adequate control for Calretinin, CDX-2, CK7, CK20, CK5/6, ER, GCDFP-15, mammoglobin, MOC-31, Napsin-A, p63, PAX-8, S100, TTF-1, and Villin.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show an adenocarcinoma histologically similar to that seen in part A.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show an adenocarcinoma histologically similar to that seen in part A.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections show an adenocarcinoma histologically similar to that seen in part A.

An intradepartmental consultation was obtained with Dr. [REDACTED]

Source: NCI Genomic Data Commons file 736c0b0c-b629-401d-b39f-218c9a0c7e61 (TCGA-55-7816.CA0D6F7A-FEE3-49C5-8239-8A2583CECDD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).